Somatic mutation profile of tumor specimen 0DFF75 from CCDI case PBBNZV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.3 years (3,767 days).
Specimen 0DFF75: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 911f9751-ca29-4250-835b-af02329626c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFF6Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e40cb85-dc5d-4059-8193-6cc39f4f61e7

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 72/519 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761380652; called by muse, mutect2, varscan2
- ESPNL | c.1969G>A p.G657S | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.324); catalogued as rs749075192; called by muse, mutect2
- FAN1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 106/377 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs138307818; called by muse, mutect2, varscan2
- RGL3 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as rs1421168851; called by muse, mutect2
- CHSY3 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.6436G>A p.V2146I | Missense Mutation (SNP) | VAF 14/439 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.024); called by muse, mutect2
- MAP1A | c.2627C>G p.P876R | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 12/412 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- CPM | c.306C>T p.T102= | Silent (SNP) | VAF 96/343 reads (28%) | called by muse, mutect2, varscan2
